CPTAC case 11CO027 — Colon — Adenomas and Adenocarcinomas (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/4427bb34-26c9-45e3-84ab-a2bb27f24062

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 5da00abd-5fa7-4deb-95f1-7982e0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 7afb9ddb-f1c1-40ac-9873-a34cc9: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
